Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A66D, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A66D-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Surgicals

Surgical Pathology Consultation / Department of Pathology

[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

ICD-O-3
Astrocytoma, anaplastic 9401/3
Site ^{RPT} Brain, overlapping lesion C71.8
C64.4 Brain, supratentorial NC
Jd 5/10/13 C71.0

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

- A. Brain tumor [REDACTED]
- A. P53 Protein [REDACTED]
- A. Phosphohistone-H3 [REDACTED]
- A. Glial Fibrill. Acid Prt [REDACTED]
- A. Isocitrate dehydrogenase 1 [REDACTED]
- A. KI-67, Nuclear Antigen, Mib1 [REDACTED]
- A. Frozen Section Charge
- CLINICAL HISTORY: A year old, white female here for right craniotomy for brain tumor.

DIAGNOSIS:

A. "Brain tumor, right posterior frontal, craniotomy for resection":

Anaplastic astrocytoma, WHO Grade III (See comment)
COMMENT: Sections show an infiltrating glioma with prominent nuclear and cellular pleomorphism and non-uniformity and a microcystic background. Many tumor cells display gemistocytic morphology. Focally, the tumor appears to extend into the subarachnoid space (slides "A5" and "A6"). Mitoses are easily identified on routine H&E sections and immunostudy for the mitoses specific antibody PHH3 reveals a maximum of 7 mitoses per 10 high power fields. Ki-67 (MIB-1) shows an elevated proliferation index of up to 10-15% approximately. Tumor cells and tumor cell processes are strongly immunoreactive for GFAP. The tumor is positive for mutated isocitrate dehydrogenase 1 (IDH1). P53 is immunoreactive in the majority of tumor cells (more than 50%). There is focal individual tumor cell necrosis; however, definitive areas of geographic or pseudopalisading necrosis are not seen in the sections examined. Definitive microvascular proliferation is not identified in this material. These findings support the diagnosis of anaplastic astrocytoma (WHO Grade III). Clinicopathologic correlation is recommended.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and hospital #

- A. Brain tumor
- A. The specimen is received fresh for frozen section, designated "Brain tumor" and consists of a 6.2 x 4.0 x 1.5 cm, irregular fragment of tan-white soft tissue admixed with blood clot. Sectioning through this tissue reveals a gray-tan to tan-white, ill-defined cut surface. A representative piece is submitted for frozen section evaluation, FSA1. Frozen section diagnosis is "Diffuse infiltrating glioma," [REDACTED]. Residual frozen section tissue is submitted in cassette FSA1 and the remaining tissue is submitted entirely in cassettes A2-A9. A portion of the specimen was frozen for the brain bank. [REDACTED]. "I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic

[page 2 of 2]
examination on all referenced material. I have personally issued this report on the basis of the gross and microscopic findings."

[REDACTED]

[REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]
Pathologist
[REDACTED]

Source: NCI Genomic Data Commons file 53698d8c-7161-42b3-97f4-392c79d6c89e (TCGA-DH-A66D.44D22FE9-2B47-4638-A97F-3C89890D9504.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).